Somatic mutation profile of tumor specimen TCGA-AA-3495-01A (aliquot TCGA-AA-3495-01A-01D-1408-10) from TCGA case TCGA-AA-3495, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 79.1 years (28,886 days).
Specimen TCGA-AA-3495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b5d25b9-5287-4f74-8a1b-8a6d7111764e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3495-11A (Solid Tissue Normal), aliquot TCGA-AA-3495-11A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc1bbbf2-2e36-483b-8e11-7b1ff6715eac

The open-access MAF lists 133 somatic variants for this specimen: 88 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 44, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 10/55 reads (18%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3055G>A p.G1019R | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762595407, COSV52197616; called by muse, mutect2, varscan2
- AC100868.1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs775066233, COSV51840918; called by muse, mutect2
- AKAP9 | c.10042G>A p.A3348T (on ENST00000359028; = p.A3324T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs182048899; called by muse, mutect2, varscan2
- ALK | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.997); catalogued as rs572340007, COSV66557726, COSV66593660, COSV66594689; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ARHGAP39 | c.2911C>T p.R971W (on ENST00000276826 / NM_001308208.2; = p.R1002W on NM_025251.2) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52769023; called by muse, mutect2, varscan2
- ARID2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV57600995, COSV57610003; called by muse, mutect2, varscan2
- ATAT1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.564); catalogued as rs559725768; called by muse, mutect2, varscan2
- ATP13A5 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60873635; called by muse, mutect2, varscan2
- ATP1B2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as rs770644298, COSV51516013; called by muse, mutect2, varscan2
- ATP6V1E1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1191953761, COSV53657009, COSV99494162; called by muse, mutect2, varscan2
- BANK1 | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as rs759883744; called by muse, mutect2, varscan2
- BRINP1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs762594427; called by muse, mutect2, varscan2
- CDYL2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768656038, COSV101629636; called by muse, mutect2, varscan2
- CEP162 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138324166, COSV57617396; called by muse, mutect2, varscan2
- CFHR4 | c.1093C>G p.P365A (on ENST00000367416 / NM_001201551.2; = p.P119A on NM_006684.5) | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.338); catalogued as COSV52231730, COSV99260033; called by muse, mutect2, varscan2
- CHST11 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759769235; called by muse, mutect2, varscan2
- CMYA5 | c.10630G>T p.A3544S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV71407391; called by muse, mutect2, varscan2
- COG5 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs370851836; called by mutect2, varscan2
- COL6A1 | c.2953G>A p.V985I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.234); catalogued as rs781394145, COSV62612356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEF8 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs977015766; called by muse, mutect2, varscan2
- DISP2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763167909; called by muse, mutect2, varscan2
- DOCK6 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs371409446, COSV53912474; called by muse, mutect2, varscan2
- DPP10 | c.1259C>A p.S420* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV59700764; called by muse, mutect2, varscan2
- DUOX1 | c.3881G>A p.R1294Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746050550, COSV58477409; called by muse, mutect2, varscan2
- EBF1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs988910682, COSV58176135; called by muse, mutect2, varscan2
- EDIL3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908131; called by muse, mutect2, varscan2
- ELAVL4 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs755538583, COSV63915662; called by muse, mutect2, varscan2
- FAM47B | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs778028004, COSV61453478; called by muse, mutect2, varscan2
- FURIN | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99184617; called by mutect2, varscan2
- HTR2C | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1556468184, COSV52210673; called by muse, mutect2, varscan2
- INCENP | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140202170; called by muse, mutect2, varscan2
- KIAA1109 | c.9385T>G p.S3129A | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.952); catalogued as rs758134216; called by muse, mutect2, varscan2
- KRTAP12-1 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs200130684, COSV59969601; called by muse, mutect2, varscan2
- LRRC32 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.258); catalogued as COSV52633951; called by muse, mutect2, varscan2
- MSN | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV64303161; called by muse, mutect2, varscan2
- MYO18B | c.3008C>A p.P1003Q | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100125691, COSV59139709; called by muse, mutect2, varscan2
- NOTCH1 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.22); catalogued as rs773926521; called by muse, mutect2, varscan2
- OPRM1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376950705, CM016141, COSV57686154; called by muse, mutect2, varscan2
- OR6C4 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV67792784; called by muse, mutect2, varscan2
- PAK6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs752441056, COSV53046942; called by mutect2, varscan2
- PCDHA11 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100247543; called by muse, mutect2, varscan2
- PCDHA11 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as COSV56475254; called by muse, mutect2, varscan2
- PCDHGA11 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs767148055, COSV53916346; called by muse, mutect2, varscan2
- PCDHGB2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV53971022, COSV54018191; called by muse, mutect2, varscan2
- PIAS3 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as rs868988923, COSV65171507; called by muse, mutect2, varscan2
- PITX2 | c.283C>T p.Q95* (on ENST00000354925 / NM_001204397.1; = p.Q102* on NM_000325.6) | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV60740860; called by muse, mutect2, varscan2
- PPP2R3A | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs762895388, COSV53871696; called by muse, mutect2
- PRKAR1A | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV62236041; called by muse, mutect2
- PROKR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146544539; ClinVar: likely benign; called by muse, mutect2, varscan2
- PYGO2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs977306770, COSV63757306; called by muse, mutect2, varscan2
- RAD50 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs757836195, COSV54748758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD3 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs971017913; called by muse, mutect2, varscan2
- TAF1L | c.4208C>T p.T1403M | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs778395226, COSV54260622; called by muse, mutect2, varscan2
- TLE4 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs771669600; called by muse, mutect2
- TNFRSF11B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375274060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13D | c.3688G>A p.V1230I | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs778915150; called by muse, mutect2, varscan2
- ZFPM2 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV68282594; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKRD26 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4473del p.F1491Lfs*16 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- CACNB1 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CDK1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2
- DAGLB | c.1969dup p.A657Gfs*37 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- FXR1 | c.1621A>G p.I541V | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- GBA2 | c.165del p.E56Rfs*13 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- HECTD4 | c.9569_9571del p.R3190del | In Frame Del (DEL) | VAF 14/30 reads (47%) | called by pindel, varscan2
- HLA-DRA | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HMCN1 | c.11957-2A>G p.X3986_splice | Splice Site (SNP) | VAF 22/82 reads (27%) | called by mutect2, varscan2
- LRRK2 | c.7049G>T p.S2350I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, varscan2
- MTHFD2 | c.558_562+3delinsC p.X186_splice | Splice Site (DEL) | VAF 24/96 reads (25%) | called by pindel, varscan2*
- MYH8 | c.1789C>A p.L597M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR13G1 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR3A1 | c.680C>A p.A227E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PLEKHO2 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RABGAP1L | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- SACS | c.4337C>T p.P1446L | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SLC37A1 | c.1017del p.K340Sfs*46 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- TMEM82 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TNPO2 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- TP53I3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- UBE2F | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UPP2 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZDHHC1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF205 | c.1416del p.E473Rfs*64 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- ZNF74 | c.832_835dup p.D279Vfs*3 | Frame Shift Ins (INS) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- ZNF831 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABTB2 | c.2109C>T p.S703= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs771693284, COSV100130530; called by muse, mutect2, varscan2
- ALX4 | c.567G>T p.G189= | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- AOC3 | c.705C>T p.G235= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs761064515, COSV53826309; called by muse, mutect2, varscan2
- AP1AR | c.678C>T p.S226= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- ARHGAP32 | c.3768C>A p.T1256= (on ENST00000310343 / NM_001378025.1; = p.T907= on NM_014715.4) | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- BPNT2 | c.636C>T p.S212= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs778717032, COSV99389165; called by muse, mutect2, varscan2
- CARD11 | c.2925G>T p.R975= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CDC42EP3 | c.189C>T p.Y63= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs755416975; called by muse, mutect2, varscan2
- CDH18 | c.1500T>A p.S500= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV56938531; called by muse, mutect2, varscan2
- CDK11B | c.1917C>T p.P639= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs369093717; called by muse, mutect2, varscan2
- DCHS1 | c.8877A>G p.G2959= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- DRD3 | c.1089G>A p.E363= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- FIBCD1 | c.597C>T p.S199= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs576776257; called by muse, mutect2, varscan2
- FIGN | c.1296C>T p.D432= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs776521695; called by muse, mutect2, varscan2
- IGKV1-12 | c.210C>A p.I70= | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- ITSN2 | c.3598C>T p.L1200= | Silent (SNP) | VAF 62/188 reads (33%) | called by muse, mutect2, varscan2
- IWS1 | c.1692C>A p.I564= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs753294967, COSV54868378; called by muse, mutect2, varscan2
- LTF | c.1023C>T p.S341= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs746084299; called by muse, mutect2, varscan2
- MYLK3 | c.345C>T p.F115= | Silent (SNP) | VAF 5/27 reads (19%) | called by mutect2, varscan2
- NCKAP5 | c.336C>T p.F112= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs775961437; called by muse, mutect2, varscan2
- NEDD9 | c.1008A>T p.A336= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- NOTCH4 | c.5454G>A p.L1818= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs754360030; called by muse, mutect2, varscan2
- OR1C1 | c.165C>A p.L55= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV68716286; called by muse, mutect2, varscan2
- PCDH11X | c.123C>T p.G41= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV53456219, COSV53461674; called by muse, mutect2, varscan2
- PCDH11X | c.768C>A p.V256= | Silent (SNP) | VAF 66/120 reads (55%) | called by muse, mutect2, varscan2
- PLPPR5 | c.138C>T p.H46= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV54180168; called by muse, mutect2, varscan2
- PREX1 | c.159C>A p.V53= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2
- RIMS1 | c.4470T>C p.T1490= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ROBO4 | c.57C>T p.L19= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs1269258979, COSV100127963; called by muse, mutect2, varscan2
- ROGDI | c.555G>A p.P185= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs771793763, COSV59020737; called by muse, mutect2, varscan2
- SEMA4D | c.141C>A p.I47= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- SIRPB1 | c.681C>T p.C227= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs1383996930; called by muse, mutect2, varscan2
- SON | c.2469C>A p.S823= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- STAB1 | c.4894C>T p.L1632= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- SVIL | c.1107A>G p.Q369= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.63T>A p.I21= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- TRIB2 | c.36G>A p.A12= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs777884568; called by muse, mutect2, varscan2
- TRIM9 | c.1530C>T p.N510= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs146284438; called by muse, mutect2, varscan2
- TSPAN10 | c.537C>T p.G179= (on ENST00000574882 / NM_001290212.1; = p.G141= on NM_031945.4) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs532564510, COSV60773421; called by muse, mutect2, varscan2
- USP53 | c.705C>T p.R235= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV56794958; called by muse, mutect2
- WBP1L | c.618G>A p.L206= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1411608010; called by muse, mutect2, varscan2
- WWC1 | c.3144G>A p.E1048= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- ZFHX3 | c.24C>T p.V8= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs775146790, COSV99213289; called by muse, mutect2, varscan2
- ZNF585B | c.789C>T p.I263= | Silent (SNP) | VAF 35/193 reads (18%) | catalogued as COSV57215232; called by muse, mutect2, varscan2
- GULP1 | c.-172+4401G>A | Intron (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
